Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A25F, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A25F-01A (Primary Tumor).

[page 1 of 3]
ICB-0-3

carcinoma, infiltrating duct, Nos 8500/3

Site: breast, Nos C50.9
4/27/11

SURGICAL REPORT

Name: .
Sex: F
DOB:
Location:
Doctor:

Pathology Number:
Date Collected:
Date Received:
M.R. Number:
Account Number

PRE-OPERATIVE DIAGNOSIS

RIGHT BREAST CA

POST-OPERATIVE DIAGNOSIS

RIGHT BREAST CA

PROCEDURE

RIGHT BREAST LUMPECTOMY WITH SENTINEL LYMPH NODE BIOPSY, F.S.; POSSIBLE AXILLARY DISSECTION, POSSIBLE SAPI PREP DEVICE INSERTION

TISSUES

- A. SENTINEL LYMPH NODE (S) - RIGHT SENTINEL LYMPH NODE #1 * *
- B. SENTINEL LYMPH NODE (S) - RIGHT SENTINEL LYMPH NODE #2 * *
- C. BREAST EXCISION, NEEDLE LOC, SIMPLE, MARGINS, ETC. - RIGHT BREAST LUMP

FS DIAGNOSIS

- A. RIGHT SENTINEL LYMPH NODE #1, -
ONE NEGATIVE NODE (0/1).
- B. RIGHT SENTINEL LYMPH NODE #2, -
ONE NEGATIVE NODE (0/1).
- C. RIGHT BREAST LUMP (GROSS MARGINS) -
THE TUMOR MASS MEASURES 2.5 CM. IN MAXIMUM DIMENSION AND ALL SURGICAL MARGINS ARE FREE OF LESION.

(REPORTED TO SURGEON:

Diagnosed by:

FINAL DIAGNOSIS

- A. RIGHT SENTINEL LYMPH NODE #1 -
ONE REACTIVE LYMPH NODE (0/1).
- B. RIGHT SENTINEL LYMPH NODE #2 -
ONE REACTIVE LYMPH NODE (0/1).
- C. RIGHT BREAST LUMP -
INFILTRATIVE DUCT CARCINOMA (2.5 CM.)
SCARFF-BLOOM-RICHARDSON GRADING:
GRADE III OF III (ABSENT TUBULE FORMATIONS, HIGH GRADE NUCLEAR FEATURES AND HIGH MITOTIC INDEX).
ANGIOLYMPHATIC INVASION:

Patient Name:

Pathology Number:

SURGICAL REPORT

Page 1 of 3

[page 2 of 3]
Patient Name

Pathology Number:

**PROBABLE
DCIS/ATYPICAL DUCTAL HYPERPLASIA:
PRESENT, GIBRIFORM PATTERN, HIGH GRADE NUCLEAR FEATURES AND
COMPRISE ABOUT 6% OF THE TUMOR.
SURGICAL MARGINS:
UNINVOLVED.
NON-NEOPLASTIC BREAST:
FIBROCYSTIC CHANGES WITH MICROCALCIFICATION.
MAMMARY VESSEL MEDIAL CALCIFICATION.**

Diagnosed by: M.D., Pathologist

Reviewed and electronically signed out by:

COMMENT

The ER, PR and Her-2/neu (IHC) have been performed on surgical

This case is discussed with Dr. by Dr. --

COMMENT2

Immunohistochemical (IHC) stain for pankeratin (AE1/AE3) is negative for micrometastases in right sentinel lymph nodes (blocks FSA, A, FSB, B).

GROSS DESCRIPTION

- The specimen is received in three separate containers labeled designated A, B, C.
- A. The container is received fresh unfixed labeled "right sentinel lymph node #1 for frozen section" and consists of an ovoid mass of apparent fat which is 1 x 0.6 x 0.4 cm. Sectioning reveals a 0.3 cm. tan-gray firm nodule. Frozen section is obtained by Dr. The entire specimen including frozen section is submitted in two blocks.
- B. The container is received fresh unfixed labeled "right sentinel lymph node #2 for frozen section" and consists of an irregular mass of apparent fat which is 0.6 x 0.4 x 0.4 cm. Sectioning reveals a thin rim of tan-gray firm rubbery tissue 0.4 x 0.3 x 0.2 cm. Frozen section is obtained by Dr. The entire specimen including frozen section is submitted in two blocks.
- C. The container is received fresh unfixed labeled "right breast lump" and consists of a 26 gm. ovoid mass of apparent fatty and fibrous-encased tissue which is 5.5 x 4 x 3.5 cm. in greatest overall dimension. There are two short sutures indicating superior margin inked with red dye, inferior is inked yellow. There is a single long suture indicating lateral margin inked with green dye, medial is inked blue. There is a single short suture indicating anterior margin inked with orange dye, posterior/deep is inked black. Sectioning reveals a tumor mass 2.5 x 2.3 x 1.5 cm. in greatest overall dimension and grossly appears to be 0.4 cm. from the superior, 0.5 cm. from the inferior, 1 cm. from the lateral, 0.8 cm. from the medial, 0.8 cm. from the anterior, and 0.5 cm. from the posterior. The entire specimen is submitted in sixteen blocks.

Note: Gross margins are observed by Dr. Gross margins are free. The closest margin is superior which is about 4 mm.

Patient Name

Pathology Number:

SURGICAL REPORT

Page 2 of 3

[page 3 of 3]
Patient Name

Pathology Number:

Key Note Block Summary: 1—superior, 2—inferior, 3—lateral, 4—medial, 5—anterior, 6—posterior (all are perpendicular), 7 through 16—remaining. (fixation time 9:28 a.m.)

**MICROSCOPIC EXAM
SYNOPTIC REPORT:**

Specimen Laterality: Right
Procedure: Excision w/o wire-guided loc
Specimen Integrity: Single intact specimen
Lymph Node Sampling: Sentinel lymph nodes
Specimen Size: 5.5 x 4 x 3.5 cm.
Invasive Carcinoma Size: 2.5 cm.
Tumor Focality: Single
Extent of Tumor: Skin not present
No skeletal muscle present
In-situ Component: DCIS
Histologic Type: Ductal
Histologic Grade: 3
Glandular/Tubular Differentiation: 3
Nuclear Pleomorphism: 3
Mitotic Count: 3
Margins: Margins uninvolved by invasive carcinoma
Distance from closest margin: 4 mm, superior
Margins uninvolved by DCIS
Lymph Nodes: 2 SLN examined
2 Total LN examined
Pathologic Staging: pT2 pN0 MX
ER: 0%
PR: 2%
Her-2/neu IHC: Negative

MICROSCOPIC EXAMINATION CONDUCTED BY PATHOLOGIST CONFIRMS FINAL DIAGNOSIS.

SPECIAL STAINS PERFORMED: Cytokeratin (AE1/AE3) (specimens A&B) (

Patient Name

Pathology Number:

SURGICAL REPORT

Page 3 of 3

Source: NCI Genomic Data Commons file 63a102fa-5948-4c0b-9663-5ab47d5499da (TCGA-A2-A25F.AC60F5BB-9371-4F69-BAA0-099AD7FC2A0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).